Somatic mutation profile of tumor specimen C3N-02718-03 (aliquot CPT0178620006) from CPTAC case C3N-02718, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IA; Tumor grade: GX; Age at diagnosis: 69.1 years (25,231 days).
Specimen C3N-02718-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0d073acc-06fb-41a6-8a86-9f2aebc5efd1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02718-71 (Blood Derived Normal), aliquot CPT0178720002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/58fff0a9-15b6-49f5-b575-b510ad8a9c88

The open-access MAF lists 66 somatic variants for this specimen: 49 protein-altering or splice-affecting, 12 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 43, Silent 12, Nonsense Mutation 5, RNA 3, Intron 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCB11 | c.2624A>T p.Q875L | Missense Mutation (SNP) | VAF 9/185 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV55585924; called by muse, mutect2
- ACTR1B | c.137G>T p.R46L | Missense Mutation (SNP) | VAF 21/480 reads (4%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.983); catalogued as COSV56704993; called by muse, mutect2
- ADGRB3 | c.3369A>T p.K1123N | Missense Mutation (SNP) | VAF 8/144 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.493); catalogued as COSV53236877; called by muse, mutect2
- ALAS2 | c.187C>G p.P63A | Missense Mutation (SNP) | VAF 12/242 reads (5%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as COSV58193185; called by muse, mutect2
- ANGPT4 | c.187A>G p.R63G | Missense Mutation (SNP) | VAF 11/197 reads (6%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs1436905191; called by muse, mutect2
- DNASE1L3 | c.577G>T p.G193C | Missense Mutation (SNP) | VAF 14/182 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59156048, COSV59157672; called by muse, mutect2
- F7 | c.179G>T p.R60L | Missense Mutation (SNP) | VAF 29/821 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.607); catalogued as rs1317071286; called by muse, mutect2
- FLT3 | c.2534G>A p.R845K | Missense Mutation (SNP) | VAF 8/201 reads (4%) | SIFT tolerated (0.17); PolyPhen benign (0.078); catalogued as COSV99609378; called by muse, mutect2
- KIF12 | c.249C>G p.D83E | Missense Mutation (SNP) | VAF 17/272 reads (6%) | SIFT tolerated (0.46); PolyPhen benign (0.006); catalogued as rs1455008565; called by muse, mutect2
- KIR3DL2 | c.326C>A p.P109H | Missense Mutation (SNP) | VAF 60/611 reads (10%) | SIFT tolerated (0.67); PolyPhen probably damaging (0.999); catalogued as COSV54393432; called by muse, mutect2
- NPAS3 | c.1063G>C p.D355H (on ENST00000356141 / NM_001164749.2; = p.D323H on NM_022123.3) | Missense Mutation (SNP) | VAF 10/270 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100639519; called by muse, mutect2
- NRP2 | c.943G>T p.D315Y | Missense Mutation (SNP) | VAF 30/495 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as COSV55934876; called by muse, mutect2
- PCDHB13 | c.2134C>T p.R712W | Missense Mutation (SNP) | VAF 35/518 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.057); catalogued as COSV53401470; called by muse, mutect2
- PHF20 | c.2536G>T p.A846S | Missense Mutation (SNP) | VAF 39/332 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.21); catalogued as COSV64976496; called by muse, mutect2, varscan2
- PLCB4 | c.3496G>T p.E1166* (on ENST00000278655 / NM_182797.3; = p.R1178L on NM_000933.4 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 19/415 reads (5%) | catalogued as COSV53816676, COSV53820270; called by muse, mutect2
- TMEM94 | c.343C>T p.R115W | Missense Mutation (SNP) | VAF 20/470 reads (4%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs780837664, COSV58593015; called by muse, mutect2
- TSHR | c.1366C>A p.L456M | Missense Mutation (SNP) | VAF 21/426 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99991493; called by muse, mutect2
- ZNF536 | c.992G>A p.G331D | Missense Mutation (SNP) | VAF 42/498 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62821888; called by muse, mutect2
- ZNF773 | c.781G>T p.D261Y | Missense Mutation (SNP) | VAF 38/327 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.304); catalogued as COSV99989200; called by muse, mutect2, varscan2
- AKAP3 | c.763A>T p.R255* | Nonsense Mutation (SNP) | VAF 12/320 reads (4%) | called by muse, mutect2
- BOD1L1 | c.4327G>A p.V1443I | Missense Mutation (SNP) | VAF 10/208 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.003); called by muse, mutect2
- CHRNG | c.128C>T p.P43L | Missense Mutation (SNP) | VAF 23/712 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DBX1 | c.785A>C p.H262P | Missense Mutation (SNP) | VAF 22/475 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.949); called by muse, mutect2
- DHRS7B | c.836C>T p.A279V | Missense Mutation (SNP) | VAF 50/1499 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.759); called by muse, mutect2
- DPPA4 | c.496C>T p.P166S | Missense Mutation (SNP) | VAF 34/642 reads (5%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.857); called by muse, mutect2
- EPSTI1 | c.303A>T p.K101N | Missense Mutation (SNP) | VAF 38/651 reads (6%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); called by muse, mutect2
- FAM133A | c.311C>T p.S104F | Missense Mutation (SNP) | VAF 7/106 reads (7%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.025); called by muse, mutect2
- FBLN1 | c.1373A>T p.Y458F | Missense Mutation (SNP) | VAF 48/798 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.001); called by muse, mutect2
- GIMAP6 | c.787C>T p.P263S | Missense Mutation (SNP) | VAF 26/528 reads (5%) | SIFT tolerated (0.46); PolyPhen benign (0.001); called by muse, mutect2
- GLI4 | c.839C>A p.S280Y | Missense Mutation (SNP) | VAF 30/512 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- GPR1 | c.341C>G p.S114C | Missense Mutation (SNP) | VAF 8/194 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2
- HMGXB3 | c.2453C>G p.S818C (on ENST00000613459; = p.S572C on NM_014983.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/260 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.535); called by muse, mutect2
- HMSD | c.97G>T p.G33C | Missense Mutation (SNP) | VAF 9/102 reads (9%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.979); called by muse, mutect2
- IGHV3-15 | c.253G>T p.V85L | Missense Mutation (SNP) | VAF 19/494 reads (4%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.508); called by muse, mutect2
- ISYNA1 | c.1312C>A p.Q438K | Missense Mutation (SNP) | VAF 22/528 reads (4%) | SIFT tolerated (0.14); PolyPhen benign (0.439); called by muse, mutect2
- LRRC7 | c.145C>A p.L49M (on ENST00000651989 / NM_001370785.2; = p.L16M on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/426 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MYH2 | c.3868T>A p.S1290T | Missense Mutation (SNP) | VAF 19/620 reads (3%) | SIFT tolerated (0.09); PolyPhen benign (0.007); called by muse, mutect2
- NAGK | c.30-3T>C | Splice Region (SNP) | VAF 11/233 reads (5%) | called by muse, mutect2
- NEK11 | c.1639A>G p.T547A | Missense Mutation (SNP) | VAF 12/274 reads (4%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, mutect2
- OR2T11 | c.490C>A p.P164T | Missense Mutation (SNP) | VAF 14/386 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); called by muse, mutect2
- PBX3 | c.106G>T p.G36W | Missense Mutation (SNP) | VAF 20/368 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.682); called by muse, mutect2
- PCDH11Y | c.1855G>A p.G619S (on ENST00000400457 / NM_032973.2; = p.G608S on NM_032971.3) | Missense Mutation (SNP) | VAF 11/196 reads (6%) | SIFT tolerated (0.84); PolyPhen possibly damaging (0.823); called by muse, mutect2
- PRICKLE3 | c.1672G>T p.E558* | Nonsense Mutation (SNP) | VAF 8/140 reads (6%) | called by muse, mutect2
- PRKD2 | c.1476G>T p.Q492H | Missense Mutation (SNP) | VAF 47/364 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0.439); called by muse, mutect2, varscan2
- SPHKAP | c.4652C>A p.A1551D | Missense Mutation (SNP) | VAF 19/379 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); called by muse, mutect2
- TRABD2A | c.188A>G p.Y63C | Missense Mutation (SNP) | VAF 24/342 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- TUBA3C | c.1164G>A p.W388* | Nonsense Mutation (SNP) | VAF 16/574 reads (3%) | called by muse, mutect2
- UMPS | c.604C>T p.Q202* | Nonsense Mutation (SNP) | VAF 12/344 reads (3%) | called by muse, mutect2
- ZKSCAN2 | c.827A>G p.N276S | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT tolerated (0.74); PolyPhen benign (0.003); called by muse, mutect2
- ALDH3B2 | c.507C>A p.V169= | Silent (SNP) | VAF 10/243 reads (4%) | called by muse, mutect2
- CA8 | c.669C>G p.T223= | Silent (SNP) | VAF 38/604 reads (6%) | called by muse, mutect2
- ELAPOR1 | c.2307G>T p.V769= | Silent (SNP) | VAF 11/323 reads (3%) | called by muse, mutect2
- ERAP2 | c.1725T>G p.P575= | Silent (SNP) | VAF 8/198 reads (4%) | called by muse, mutect2
- FAM89A | c.126C>T p.G42= | Silent (SNP) | VAF 14/410 reads (3%) | catalogued as rs1353317058; called by muse, mutect2
- KIR3DL2 | c.327C>A p.P109= | Silent (SNP) | VAF 61/604 reads (10%) | called by muse, mutect2
- OR8B8 | c.810G>A p.Q270= | Silent (SNP) | VAF 15/381 reads (4%) | called by muse, mutect2
- RALGDS | c.42C>T p.G14= | Silent (SNP) | VAF 15/454 reads (3%) | catalogued as rs1396553581; called by muse, mutect2
- SLC22A6 | c.861C>A p.A287= | Silent (SNP) | VAF 15/408 reads (4%) | called by muse, mutect2
- SPHKAP | c.4653C>A p.A1551= | Silent (SNP) | VAF 20/385 reads (5%) | called by muse, mutect2
- TECTA | c.594C>T p.P198= | Silent (SNP) | VAF 24/536 reads (4%) | called by muse, mutect2
- TRPC5OS | c.201C>A p.L67= | Silent (SNP) | VAF 12/187 reads (6%) | called by muse, mutect2
- AC024940.1 | n.3491G>T | RNA (SNP) | VAF 8/153 reads (5%) | called by muse, mutect2
- AC024940.1 | n.3490T>A | RNA (SNP) | VAF 8/155 reads (5%) | called by muse, mutect2
- LINC02693 | n.752G>A | RNA (SNP) | VAF 54/519 reads (10%) | called by muse, mutect2
- MYB | c.1203+1238T>C | Intron (SNP) | VAF 19/308 reads (6%) | called by muse, mutect2
- PRICKLE3 | c.43-40G>A | Intron (SNP) | VAF 14/201 reads (7%) | called by muse, mutect2
